Surgical pathology report (de-identified scan), TCGA case TCGA-63-5131, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Ontario Institute for Cancer Research, specimen TCGA-63-5131-01A (Primary Tumor).

Sample Number	Sample Type	Sample Preparation	Site of Tissue	Diagnosis	Year of Sample Collection	Age at Sample Collection (yrs)	Sample Comments	Days to Procedure Date	Days to Diagnosis	Type of Procedure	Site of Primary (Histology)	Tumour Size (cm)	Histology	Grade/ Differentiation	Pathological T	Pathological N	Clinical M	VALSG Stage	Histology Comments	Slide Image
	TUMOUR	FF	RL	Squamous carcinoma						RESECT	RLNOS	13.90	07	II	T2,NOS	N1	M0			
	BUFFY	FF		Squamous carcinoma						RESECT	RLNOS	13.93	07	II	T2,NOS	N1	M0			

Source: NCI Genomic Data Commons file 9371fd42-512e-41a1-a919-38218afef2c5 (TCGA-63-5131.DE9FB170-D3D9-4642-A3D3-60639889DF2D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).